Surgical pathology report (de-identified scan), TCGA case TCGA-UC-A7PF, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site University of Washington, specimen TCGA-UC-A7PF-01A (Primary Tumor).

[page 1 of 3]
Patient ID: _
Collected: _
Received: _

ICD-O-3
Carcinoma, squamous cell NOS
8070/3
Site Cervix NOS
C53.9
9/27/13

SPECIMEN(S): Lymph node sampling
SPECIMEN(S): Lymph node sampling
SPECIMEN(S): Lymph node sampling
SPECIMEN(S): Ovary, left
SPECIMEN(S): Lymph node sampling
SPECIMEN(S): Lymph node sampling
SPECIMEN(S): Lymph node sampling
SPECIMEN(S): Soft tissue mass biopsy
SPECIMEN(S): Uterus
SPECIMEN(S): Surgical margins
SPECIMEN(S): Surgical margins
SPECIMEN(S): Appendix, incidental

CLINICAL DATA:
Cervical cancer.

GROSS DESCRIPTION:

A) Received in formalin designated "right external iliac node" are multiple fragments of fatty tissue measuring 2 x 2 x 1 cm in aggregate. Three potential lymph nodes are identified and submitted in cassette A1.
B) Received in formalin designated "right obturator node" are multiple fragments of fatty tissue measuring 3 x 2 x 1 cm in aggregate. Several potential lymph nodes are identified and submitted in cassette B1.
C) Received in formalin designated "right common para-aortic nodes" are multiple fragments of soft tissue measuring 1 x 1 x 1 cm. No lymph nodes are identified and the specimen is entirely submitted in cassette C1.
D) Received in formalin designated "left ovary" is an ovary without attached tube measuring 3.5 x 3 x 2.5 cm. Multiple cysts (up to 0.8 cm) and adhesions are identified on the surface. The specimen is bivalved and cut surfaces reveal a cyst measuring 1 cm. Representative sections are submitted in cassettes D1 and D2.
E) Received in formalin designated "left external iliac nodes" are multiple fragments of fatty tissue measuring 4 x 2 x 1 cm in aggregate. Several potential lymph nodes are identified and submitted in cassettes E1-E3.
F) Received in formalin designated "left obturator nodes" are multiple fragments of fatty tissue and blood clot. No lymph nodes are identified and the specimen is entirely submitted in cassettes F1 and F2.

[page 2 of 3]
G) Received in formalin designated "left common iliac nodes" are multiple fragments of fatty tissue measuring 2 x 1 x 0.8 cm in aggregate. One lymph node

is identified and submitted in cassette G1.

H) Received in formalin designated "right parametria" is a fragment of fibroadipose tissue measuring 2 x 2 x 0.5 cm in aggregate. The specimen is submitted in toto in cassette H1.

I) Received in formalin designated "uterus, tube, ovary and parametrium" is a

uterus with attached ovary and fallopian tube measuring 11 x 6 x 5 cm and weighs

190 grams. The uterus is covered with pink, smooth, glistening serosa with no

focal lesions identified. The ectocervix has a pink, smooth mucosa; the cervical canal is patent. The cervix measures 3.5 x 3.5 cm. The parametrium

area is inked as follows: anterior blue, posterior green. No lymph nodes

are identified in the parametrium. Bivalving the specimen reveals a 5 x 1.5 cm.

endometrial cavity The endometrium measures up to 0.2 cm in thickness and the

myometrium measures up to 2.5 cm. in thickness. The specimen is sectioned; sequential cut surfaces reveal multiple small leiomyomas in the myometrium measuring up to 1.5 cm in diameter. A firm, predominantly submucosal tumor mass,

which measures up to 1.5 cm in depth, 2.5 cm in length and which circumferentially involves all the quadrants of cervix, is identified within the

parenchyma of the cervix. The cut surfaces appears homogeneously white.

Grossly,

The lesion does not extend to the surgical resection margin; the nearest margin

is 0.4 cm from the lesion. Representative sections are submitted as follows: I1

vaginal cuff, anterior; I2 vaginal cuff, posterior; I3 parametrium, anterior; I4 parametrium, posterior; I5-I6 cervix, anterior left quadrant;

I7-I8 anterior right quadrant. Cassettes I9-I10 cervix posterior right

quadrant. Cassettes I11-I12 cervix posterior left quadrant. I13 lower segment of uterus; I14 uterus, fundus portion and representative sections of

leiomyoma.

J) Received in formalin designated "left post vaginal margin" is a fragment of mucosa measuring 4 x 1 x 0.5 cm. A suture is identified on one side of the specimen. The specimen is sectioned and the margin near the suture is submitted in cassette J1.

[page 3 of 3]
K) Received in formalin designated "right post vaginal margin" is a fragment of mucosa measuring 5 x 0.8 x 0.5 cm. The specimen is sectioned and submitted in toto in cassette K1.

L) Received in formalin designated "appendix" is an appendix with attached fatty tissue measuring 7.5 x 2.5 x 1.5 cm. The appendix measures 6.5 x 5 x 5 cm. The appendix is covered with pink, smooth serosa. No focal lesions are identified. Representative sections of the tip, mid portion, and resection margin are submitted in cassette L1.

FINAL DIAGNOSIS:

- A) Right external iliac node, resection: Three lymph nodes, negative for tumor.
- B) Right obturator node, resection: Six lymph nodes, negative for tumor.
- C) Right common para-aortic nodes, resection: Two lymph nodes, negative for tumor.
- D) Left ovary, resection: Serous cystadenoma (1.0 cm in diameter).
- E) Left external iliac lymph node, resection: 4 out of 13 lymph nodes positive for metastatic tumor.
- F) Left obturator nodes, resection: Four lymph nodes, negative for tumor.
- G) Left common iliac nodes, resection: One negative lymph node.
- H) Right parametrium, resection: Fibroadipose tissue; no evidence of malignancy.
- I) Uterus, tubes, ovaries, and parametrium, resection: Moderately-differentiated squamous cell carcinoma of the cervix with the following features:
1. Proportionate depth of invasion: Maximum depth of invasion is 88% of the 1.7 cm thick wall (1.5/1.7 cm); tumor is circumferential.
2. Parametrium: One positive lymph node in anterior parametrium; no tumor invasive of soft tissue of the parametrium.
3. All surgical margins are free of tumor; nearest margin 0.2 cm from the tumor; vaginal cuff resection margin free of tumor.
4. Microscopic angiolymphatic invasion is present.
- J) Left post-vaginal margin, resection: Negative for tumor.
- K) Right post-vaginal margin, resection: Negative for tumor.
- L) Appendix, resection: Appendix without diagnostic abnormality.

Rendering Diagnostician:

Pathologist

Electronically Signed

In compliance with . regulations, the pathologists signature on this report

indicates that the case has been personally reviewed, and the diagnosis made or

confirmed by, the Attending Pathologist

Source: NCI Genomic Data Commons file 79cbf5df-43c5-47e6-a46e-0ae475a7009a (TCGA-UC-A7PF.EF390F2F-A13F-4661-86C6-2679E4FAEE72.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).